Gene-level copy-number profile of tumor specimen HTMCP-03-06-02110-01A from CGCI case HTMCP-03-06-02110, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 44.8 years (16,353 days).
Specimen HTMCP-03-06-02110-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 50a0da60-ab9b-4e34-8a32-3ea48f851bae.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02110-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/19c4fe39-9546-41f8-abc0-e721ac31bba8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 327; copy number 2: 25,056; copy number 3: 20,748; copy number 4: 11,195; copy number 5: 5; copy number 6: 2; copy number 7: 10; copy number 9: 1,037; copy number 10: 21.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,075 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:161,581,339–161,678,654, 5 genes, copy number 7 (within-gene range 4–8): FCGR2C, HSPA7, RPS23P9, FCGR3B, FCGR2B.
- chr1:209,367,662–209,432,838, 3 genes, copy number 7: LINC01698, MIR205HG, MIR205.
- chr2:16,149,251–16,149,394, 1 gene, copy number 5: AC174048.1.
- chr3:135,925,891–195,620,233, 966 genes, copy number 9–10 (broad region; genes not listed).
- chr3:195,720,884–198,123,232, 94 genes, copy number 7–9 (within-gene range 4–9) (broad region; genes not listed).
- chr6:166,275,462–166,277,077, 1 gene, copy number 5: AL121956.5.
- chr19:27,638,483–27,646,483, 2 genes, copy number 6: ERVK-28, AC112702.1.
- chr20:5,292,388–5,316,954, 2 genes, copy number 5: UBE2D3P1, PROKR2.
- chr20:5,346,006–5,346,160, 1 gene, copy number 5: RNA5-8SP7.

Autosomal genes at a single copy (total copy number 1): 302. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
